Somatic mutation profile of tumor specimen TCGA-OR-A5JY-01A (aliquot TCGA-OR-A5JY-01A-31D-A29I-10) from TCGA case TCGA-OR-A5JY, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 69.0 years (25,190 days).
Specimen TCGA-OR-A5JY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b581b1b-f072-43b4-82e8-e4441dd99420.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JY-10A (Blood Derived Normal), aliquot TCGA-OR-A5JY-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf8a3523-6ec8-471f-8ba6-84519d26c078

The open-access MAF lists 67 somatic variants for this specimen: 54 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 12, Frame Shift Del 3, Nonsense Mutation 3, Splice Region 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 77/146 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PKHD1 | c.1774C>T p.R592* | Nonsense Mutation (SNP) | VAF 66/202 reads (33%) | catalogued as rs779050294, CM051131, COSV100583069; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATR | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV63384749; called by muse, mutect2, varscan2
- C12orf65 | c.309G>T p.Q103H | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs573747271; called by muse, mutect2, varscan2
- C6 | c.2652G>T p.L884F | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs892712339; called by muse, mutect2, varscan2
- CALB2 | c.368G>C p.R123T | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.781); catalogued as COSV56938350, COSV56939615; called by muse, mutect2, varscan2
- CHRFAM7A | c.633G>C p.M211I | Missense Mutation (SNP) | VAF 78/2080 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV55397611; called by muse, mutect2
- CREB3L3 | c.1281T>A p.N427K | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); catalogued as COSV50219415; called by muse, mutect2, varscan2
- DDX53 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 89/309 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60068610; called by muse, mutect2, varscan2
- EPB41 | c.2263G>A p.V755I (on ENST00000343067 / NM_001166005.2; = p.V513I on NM_004437.4) | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.183); catalogued as rs750558736; called by muse, mutect2, varscan2
- FLG2 | c.6410G>C p.G2137A | Missense Mutation (SNP) | VAF 93/372 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV101165786; called by muse, mutect2, varscan2
- KRTAP13-1 | c.254C>A p.T85N | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.989); catalogued as COSV100819956; called by muse, mutect2, varscan2
- NOS3 | c.1933C>G p.L645V | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV52496738; called by muse, mutect2, varscan2
- PABPC1L | c.741C>T p.A247= | Splice Region (SNP) | VAF 50/130 reads (38%) | catalogued as rs556604143, COSV53842423; called by muse, mutect2, varscan2
- PRKAR1A | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 33/53 reads (62%) | catalogued as COSV62235478; called by muse, mutect2, varscan2
- RHBDF1 | c.2476C>T p.P826S | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs1473959563; called by muse, mutect2, varscan2
- RTL6 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV57979617; called by muse, mutect2, varscan2
- SLC28A3 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs753005525; called by muse, mutect2, varscan2
- SSPN | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 57/322 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99658574; called by muse, mutect2, varscan2
- TKT | c.627C>T p.F209= | Splice Region (SNP) | VAF 26/59 reads (44%) | catalogued as rs140465934; called by muse, mutect2, varscan2
- VIPR1 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as COSV57297984; called by muse, mutect2, varscan2
- AMTN | c.337A>G p.I113V | Missense Mutation (SNP) | VAF 330/532 reads (62%) | SIFT tolerated (0.36); PolyPhen benign (0.028); called by muse, varscan2
- ARRB2 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CHPT1 | c.145T>G p.Y49D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- CMYA5 | c.3553G>A p.E1185K | Missense Mutation (SNP) | VAF 41/330 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CORO1C | c.391_394del p.K131Efs*36 | Frame Shift Del (DEL) | VAF 29/139 reads (21%) | called by mutect2, pindel, varscan2
- CRIM1 | c.2468G>C p.G823A | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- CSF2RA | c.762G>T p.Q254H | Missense Mutation (SNP) | VAF 284/649 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CYP2U1 | c.408_417del p.R137Wfs*20 | Frame Shift Del (DEL) | VAF 39/157 reads (25%) | called by mutect2, pindel, varscan2
- DLG2 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DSC2 | c.171C>A p.C57* | Nonsense Mutation (SNP) | VAF 57/129 reads (44%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.3650A>T p.E1217V | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FDFT1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 147/255 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- FGF19 | c.358T>G p.C120G | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR173 | c.481G>C p.D161H | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GTDC1 | c.875+1G>T p.X292_splice | Splice Site (SNP) | VAF 56/118 reads (47%) | called by muse, mutect2, varscan2
- GUCY1A1 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- H4C2 | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HECA | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- HMCN1 | c.15979G>C p.A5327P | Missense Mutation (SNP) | VAF 88/173 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOOK1 | c.288G>C p.Q96H | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2
- KIF1A | c.176A>T p.H59L | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- KMT2A | c.5757G>C p.K1919N | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LHFPL5 | c.388T>G p.C130G | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MEPE | c.1152A>T p.K384N | Missense Mutation (SNP) | VAF 73/573 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- NCKAP5 | c.4306A>G p.T1436A | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.009); called by muse, mutect2
- PLEKHG6 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PRX | c.121_122del p.G41Nfs*109 (on ENST00000324001 / NM_181882.3; = p.G41Nfs*91 on NM_020956.2) | Frame Shift Del (DEL) | VAF 39/116 reads (34%) | called by mutect2, pindel, varscan2
- SLC10A5 | c.925C>G p.L309V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- TNS3 | c.1427A>T p.D476V | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRAPPC12 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 112/326 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- TRGC2 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UTP18 | c.1011A>T p.R337S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZFPM2 | c.2152C>G p.L718V | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ABR | c.1074A>G p.P358= (on ENST00000302538 / NM_021962.5; = p.P321= on NM_001092.5) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs746438527; called by muse, mutect2, varscan2
- ASPN | c.288C>A p.V96= | Silent (SNP) | VAF 33/90 reads (37%) | called by muse, mutect2, varscan2
- CEP128 | c.1341G>T p.L447= | Silent (SNP) | VAF 27/146 reads (18%) | called by muse, mutect2, varscan2
- EPHB6 | c.2472T>C p.C824= | Silent (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2, varscan2
- GRK2 | c.363G>A p.S121= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs112675049; called by mutect2, varscan2
- MYT1 | c.1224G>T p.L408= | Silent (SNP) | VAF 38/153 reads (25%) | called by muse, mutect2, varscan2
- PLA2G4C | c.555G>A p.E185= | Silent (SNP) | VAF 40/144 reads (28%) | catalogued as rs754344695; called by muse, mutect2, varscan2
- PRELP | c.597C>T p.L199= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as COSV100557963; called by muse, mutect2, varscan2
- RESF1 | c.1167A>G p.A389= | Silent (SNP) | VAF 105/240 reads (44%) | called by muse, mutect2, varscan2
- RGP1 | c.957C>A p.S319= | Silent (SNP) | VAF 37/132 reads (28%) | catalogued as rs1305033059; called by muse, mutect2, varscan2
- TPX2 | c.2223C>T p.F741= | Silent (SNP) | VAF 42/168 reads (25%) | called by muse, mutect2, varscan2
- WLS | c.486C>T p.C162= | Silent (SNP) | VAF 58/124 reads (47%) | called by muse, mutect2
- ECPAS | chr9:111484671 T>C | 5'Flank (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
